Somatic mutation profile of tumor specimen ALCH-AEUL-TTP1-A (aliquot ALCH-AEUL-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEUL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,225 days).
Specimen ALCH-AEUL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4f606d2-84f4-45f0-b57e-d0efde807b31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUL-NB1-A (Blood Derived Normal), aliquot ALCH-AEUL-NB1-A-2-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f630c6-02d5-4724-9a08-ffa5c49dc199

The open-access MAF lists 482 somatic variants for this specimen: 340 protein-altering or splice-affecting, 86 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 287, Silent 86, Nonsense Mutation 23, RNA 20, Intron 18, Frame Shift Del 11, 5'UTR 9, Splice Site 8, 3'UTR 6, Splice Region 4, In Frame Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 14/288 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748839211, COSV67798212; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 113/353 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB5 | c.2441G>A p.G814D (on ENST00000404938 / NM_001163941.2; = p.G369D on NM_178559.6) | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99329678; called by muse, mutect2, varscan2
- ABI1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs767441898; called by muse, mutect2, varscan2
- ASTN2 | c.1705G>T p.G569C (on ENST00000313400 / NM_001365069.1; = p.G518C on NM_014010.5) | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57782056; called by muse, mutect2, varscan2
- ASXL3 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.985); catalogued as COSV52485045; called by muse, mutect2, varscan2
- BPI | c.59T>C p.V20A (on ENST00000262865; = p.V16A on NM_001725.3) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1220922932; called by muse, mutect2
- CACNA1H | c.4423G>C p.A1475P | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1344413563; called by muse, mutect2, varscan2
- CAMK2A | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.415); catalogued as COSV100804587; called by muse, mutect2, varscan2
- CAPN8 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64817226; called by muse, mutect2, varscan2
- CASKIN1 | c.3109C>G p.P1037A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV58214811; called by muse, mutect2, varscan2
- CD40LG | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 220/464 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM962549, CS050421, CS982109, COSV101033577; called by muse, mutect2, varscan2
- CELSR3 | c.4078C>T p.R1360W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs770480060; called by muse, mutect2, varscan2
- CEP290 | c.3405G>T p.R1135S | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58350663; called by muse, mutect2, varscan2
- CHRNB1 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.329); catalogued as rs754282990; called by muse, mutect2, varscan2
- CLIP1 | c.4199C>T p.S1400L (on ENST00000620786 / NM_001247997.1; = p.S1389L on NM_002956.2) | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs965447390, COSV100211850; called by muse, mutect2, varscan2
- CPA1 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.156); catalogued as COSV50575045, COSV99163402; called by muse, mutect2, varscan2
- CSMD2 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 61/242 reads (25%) | catalogued as COSV53880885; called by muse, mutect2, varscan2
- DCPS | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 20/119 reads (17%) | catalogued as rs1279077524, COSV55012115; called by muse, mutect2, varscan2
- DDHD1 | c.190G>T p.G64C (on ENST00000323669; = p.G295C on NM_030637.3) | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60361299; called by muse, mutect2
- DDX21 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs926485610; called by muse, mutect2
- DEPDC1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.694); catalogued as rs1475480456, COSV63958245; called by muse, mutect2, varscan2
- DMD | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 77/332 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV55860106, COSV55862429; called by muse, mutect2, varscan2
- DNAH14 | c.4922G>A p.G1641E (on ENST00000445597; = p.G2046E on NM_001367479.1) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV70543248; called by muse, mutect2
- DNAI2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1039980393, COSV56762488; called by muse, mutect2, varscan2
- DOCK4 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 42/535 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs367626411; called by muse, mutect2
- DRC7 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV61057547; called by muse, mutect2, varscan2
- DRP2 | c.2159G>T p.R720L | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV65810708; called by muse, mutect2, varscan2
- DSC3 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64572599, COSV64575131; called by muse, mutect2, varscan2
- DUOX1 | c.2299T>C p.F767L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58477256; called by muse, mutect2
- ERBB4 | c.2545G>T p.V849F | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61479616; called by muse, mutect2, varscan2
- FAM120C | c.3013G>T p.G1005* | Nonsense Mutation (SNP) | VAF 86/276 reads (31%) | catalogued as COSV60262974; called by muse, varscan2
- FH | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as COSV63817526; called by muse, mutect2
- FOXL2NB | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as rs1360345164; called by muse, mutect2
- FTMT | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58420388, COSV58421141; called by muse, mutect2, varscan2
- GABRA4 | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs759960611; called by muse, mutect2
- GALNT2 | c.1386C>G p.H462Q | Missense Mutation (SNP) | VAF 47/443 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.109); catalogued as COSV64197722; called by muse, mutect2
- GJD4 | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV100397381; called by muse, mutect2, varscan2
- GNAS | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.446); catalogued as rs201265922; called by muse, mutect2
- GRIN2A | c.1674G>A p.W558* | Nonsense Mutation (SNP) | VAF 121/536 reads (23%) | catalogued as rs1555493581, COSV100409759; called by muse, mutect2, varscan2
- GTF2H5 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs777480675; called by muse, mutect2
- HCN4 | c.3493C>A p.L1165M | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV56080986, COSV99983978; called by muse, mutect2, varscan2
- HECW1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs776309881, COSV67830108, COSV67842023; called by muse, mutect2, varscan2
- HMCN2 | c.5395G>A p.G1799R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.903); catalogued as rs903826196; called by muse, mutect2, varscan2
- IGKV3D-20 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs747231469; called by muse, mutect2, varscan2
- IQSEC3 | c.1123G>A p.G375S (on ENST00000538872 / NM_001170738.2; = p.G72S on NM_015232.1) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs781821055; called by muse, mutect2, varscan2
- ITIH5 | c.136-2A>G p.X46_splice | Splice Site (SNP) | VAF 36/96 reads (38%) | catalogued as COSV56917074; called by mutect2, varscan2
- JAG2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs587684377; called by muse, mutect2, varscan2
- KAT6B | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 209/514 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1362389122, COSV99767280; called by muse, mutect2, varscan2
- KCNA5 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs780056840, COSV104383717; called by muse, mutect2, varscan2
- KIF17 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929656; called by muse, mutect2, varscan2
- KIF2B | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs760584559; called by muse, mutect2, varscan2
- LAMA4 | c.1156G>T p.E386* (on ENST00000230538 / NM_001105206.3; = p.E379* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 114/346 reads (33%) | catalogued as COSV57903601; called by muse, mutect2, varscan2
- LINGO2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as rs1040309410, COSV58064985; called by muse, mutect2
- LMO3 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53780911; called by muse, mutect2, varscan2
- MAGEA3 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs1556826320; called by muse, mutect2
- MC2R | c.737C>A p.P246Q | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59619006; called by muse, mutect2, varscan2
- MSANTD3 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.839); catalogued as COSV58490938; called by muse, mutect2, varscan2
- MTNR1B | c.1023C>A p.H341Q | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV57067211; called by muse, mutect2, varscan2
- MYPN | c.3581G>T p.R1194L | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62733850; called by muse, mutect2
- NAA11 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54514211; called by mutect2, varscan2
- NBEA | c.7520G>T p.R2507L | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs925691595, COSV59767032; called by muse, mutect2, varscan2
- NDST3 | c.1136C>G p.P379R | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56627836; called by muse, mutect2, varscan2
- NEGR1 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 103/450 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as COSV60843674; called by muse, mutect2, varscan2
- NKAIN1 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.335); catalogued as rs1256036021; called by muse, mutect2
- NKAPL | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767988218, COSV59197745; called by muse, mutect2, varscan2
- NOS2 | c.3246C>A p.C1082* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100569820; called by muse, mutect2, varscan2
- NPAT | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53718086; called by muse, mutect2
- NRXN1 | c.2563C>G p.R855G | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1470931619; called by muse, mutect2, varscan2
- NSUN2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 189/316 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); catalogued as rs1367343470; called by muse, mutect2, varscan2
- NTM | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV66206711; called by muse, mutect2, varscan2
- NUP214 | c.4927T>A p.S1643T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs770768618; called by muse, mutect2, varscan2
- OR2L13 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV63549909; called by muse, mutect2, varscan2
- OR2T33 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817995; called by mutect2, varscan2
- OR5M10 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 117/397 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV73242362; called by muse, mutect2, varscan2
- OR7D4 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV58071618; called by muse, mutect2, varscan2
- OS9 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 84/215 reads (39%) | catalogued as rs749105762, COSV99233228; called by muse, mutect2, varscan2
- PADI6 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV100639965, COSV61884539; called by muse, mutect2, varscan2
- PAEP | c.498del p.W166Cfs*6 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV99478883; called by mutect2, pindel, varscan2
- PCDHAC1 | c.2287G>T p.G763C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs782673786; called by muse, mutect2, varscan2
- PCDHGC5 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315856354; called by muse, mutect2, varscan2
- PHF2 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs377079959; called by muse, mutect2
- POTEM | c.314G>C p.C105S | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.103); catalogued as COSV101304539; called by muse, varscan2
- PRR30 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV53204530; called by muse, mutect2, varscan2
- PTPRT | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1201649058, COSV61978956; called by muse, mutect2, varscan2
- PXDNL | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 115/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687032; called by muse, mutect2, varscan2
- RAE1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1250708417; called by muse, mutect2, varscan2
- RASSF2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs755440456, COSV65082183, COSV65083191; called by muse, mutect2, varscan2
- RIMS2 | c.1384C>T p.P462S (on ENST00000666250 / NM_001348490.2; = p.P270S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/662 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51654070; called by muse, mutect2
- RIMS2 | c.1492C>A p.P498T (on ENST00000666250 / NM_001348490.2; = p.P306T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/646 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs374794052; called by muse, mutect2, varscan2
- RYR1 | c.10276del p.E3426Sfs*45 | Frame Shift Del (DEL) | VAF 60/194 reads (31%) | catalogued as COSV62113838; called by mutect2, pindel, varscan2
- SEMA3E | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 118/567 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.099); catalogued as COSV57111339; called by muse, mutect2, varscan2
- SIGLEC16 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs781200730; called by muse, mutect2, varscan2
- SLC9A6 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100857961; called by muse, mutect2, varscan2
- SLX4 | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53562130; called by muse, mutect2, varscan2
- SPANXC | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 108/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1556301787; called by muse, mutect2, varscan2
- SPTB | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs375967688; called by muse, mutect2, varscan2
- TAS2R1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV66779427; called by muse, mutect2
- TG | c.8002C>A p.P2668T | Missense Mutation (SNP) | VAF 106/520 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55091890; called by muse, varscan2
- TG | c.8072G>T p.R2691L | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.089); catalogued as rs531167775, COSV99600120; called by muse, varscan2
- TLE4 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.668); catalogued as COSV54629888, COSV54635624; called by muse, mutect2, varscan2
- TLR4 | c.1316A>C p.E439A (on ENST00000355622 / NM_138554.5; = p.E399A on NM_003266.4) | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62922373, COSV62923773, COSV62924192; called by muse, mutect2, varscan2
- TMEM176B | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs958465542; called by muse, mutect2
- TP53 | c.370dup p.C124Lfs*25 | Frame Shift Ins (INS) | VAF 31/127 reads (24%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- TRIM64B | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 160/1136 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61693629; called by muse, mutect2, varscan2
- UGT2A1 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 128/452 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745551027, COSV54138996, COSV54146515; called by muse, mutect2, varscan2
- UGT2B4 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs368752727; called by muse, mutect2, varscan2
- UGT2B7 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59441770; called by muse, mutect2, varscan2
- UHRF2 | c.1991G>A p.R664K | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs913033341; called by muse, mutect2
- UTRN | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771082025, COSV100839462; called by muse, mutect2, varscan2
- WDFY3 | c.3796G>T p.G1266* | Nonsense Mutation (SNP) | VAF 41/250 reads (16%) | catalogued as COSV55709274; called by muse, mutect2, varscan2
- WDR87 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs1435165212; called by muse, mutect2, varscan2
- ZFHX4 | c.6041C>T p.P2014L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as rs1265755124, COSV51476787; called by muse, mutect2, varscan2
- ZIC1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51552148; called by muse, mutect2, varscan2
- ZNF23 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 27/277 reads (10%) | catalogued as rs756916277, COSV61841072; called by muse, mutect2, varscan2
- ZNF518B | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs1050066787; called by muse, mutect2
- ZNF709 | c.1683G>T p.E561D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV101172276; called by muse, mutect2, varscan2
- ZSWIM2 | c.1518del p.I508Yfs*34 | Frame Shift Del (DEL) | VAF 77/335 reads (23%) | catalogued as COSV54574423; called by mutect2, pindel, varscan2
- ABCC1 | c.2342C>A p.A781D | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABCC2 | c.2075A>C p.H692P | Missense Mutation (SNP) | VAF 141/324 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ACR | c.712-5G>T | Splice Region (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2
- ADAMTS12 | c.3068C>T p.P1023L | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- ADAMTS17 | c.2752G>T p.G918C | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS2 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY2 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2
- ADCY8 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADGRF2 | c.169T>G p.W57G | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRG4 | c.6467G>A p.W2156* | Nonsense Mutation (SNP) | VAF 80/354 reads (23%) | called by muse, mutect2, varscan2
- AGAP12P | n.586G>T | Splice Region (SNP) | VAF 64/641 reads (10%) | called by muse, varscan2
- AKAP6 | c.3596T>G p.L1199W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2
- ALDH1A2 | c.170T>A p.V57D | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD36 | c.1614T>G p.D538E | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- APOBEC3D | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APP | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 104/409 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ARFGEF2 | c.4191G>T p.W1397C | Missense Mutation (SNP) | VAF 275/753 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG2B | c.4826A>C p.E1609A | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATR | c.2170C>G p.L724V | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- BCAR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRWD1 | c.4865C>T p.A1622V | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2
- C1orf162 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- C4orf17 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- C4orf50 | c.225+1G>T p.X75_splice (on ENST00000324058; = p.X1307_splice on NM_001364689.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- C7 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C9orf57 | c.421A>G p.R141G (on ENST00000377024 / NM_001371610.1; = p.R119G on NM_001128618.2) | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CBLN2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC150 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CCDC154 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC62 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.429); called by muse, mutect2
- CCSER2 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, varscan2
- CEP295 | c.26A>T p.H9L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEP350 | c.5650G>A p.A1884T | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- CFAP54 | c.8655A>T p.K2885N | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CFAP58 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CFAP61 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP65 | c.1598C>G p.P533R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLDN19 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- COL20A1 | c.3070G>C p.A1024P | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CORIN | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- CORO1B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- CPED1 | c.1699+1del | Frame Shift Del (DEL) | VAF 56/302 reads (19%) | called by mutect2, pindel*, varscan2
- CTBP1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1475del p.I492Kfs*45 | Frame Shift Del (DEL) | VAF 50/227 reads (22%) | called by mutect2, pindel*, varscan2*
- CUX2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CYLC1 | c.17+1G>T p.X6_splice | Splice Site (SNP) | VAF 37/240 reads (15%) | called by muse, mutect2, varscan2
- CYP4F22 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); called by muse, mutect2
- DACT3 | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- DCC | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- DCDC1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 66/324 reads (20%) | called by muse, mutect2, varscan2
- DDX50 | c.1843A>T p.N615Y | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- DIP2C | c.4466A>T p.D1489V | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DMGDH | c.993A>C p.P331= | Splice Region (SNP) | VAF 59/215 reads (27%) | called by muse, mutect2, varscan2
- DNAH12 | c.6080A>G p.N2027S (on ENST00000351747; = p.N2046S on NM_001366028.2) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.1934T>A p.F645Y | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- DNAH6 | c.4914G>C p.Q1638H | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.4915C>T p.Q1639* | Nonsense Mutation (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- DNMT3A | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- DPY19L1 | c.1101+3A>T | Splice Region (SNP) | VAF 108/417 reads (26%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ENOX1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHA6 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ESPL1 | c.4984C>T p.Q1662* | Nonsense Mutation (SNP) | VAF 56/156 reads (36%) | called by muse, mutect2, varscan2
- ESRRG | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2
- F13B | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 220/427 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM149A | c.2308C>T p.Q770* (on ENST00000356371 / NM_001367768.2; = p.Q479* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/216 reads (12%) | called by muse, mutect2, varscan2
- FAM189A1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FAM205A | c.3440T>C p.V1147A | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.084); called by muse, mutect2
- FBXL7 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2
- FES | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLT4 | c.806C>A p.P269Q | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.183); called by muse, mutect2
- FREM3 | c.3065C>A p.T1022N | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FRG2C | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- FSIP2 | c.14762C>A p.A4921E | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- GABRQ | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GALNTL6 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.186); called by muse, varscan2
- GLB1L2 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLDC | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 97/414 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GLI1 | c.462T>A p.C154* | Nonsense Mutation (SNP) | VAF 54/167 reads (32%) | called by muse, mutect2, varscan2
- GNAO1 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GNB4 | c.204-1G>C p.X68_splice | Splice Site (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- GPRASP2 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIK5 | c.2792G>T p.R931L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GRM4 | c.406T>A p.C136S | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRM7 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2
- GRXCR1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 111/544 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GULP1 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAS3 | c.752A>C p.Y251S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HECW1 | c.2097C>A p.S699R | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HMGCS2 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 139/498 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- HSD17B11 | c.764_766del p.K255del | In Frame Del (DEL) | VAF 22/202 reads (11%) | called by pindel, varscan2
- IFNA1 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGFALS | c.1724C>A p.A575E | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- IGLV2-33 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.05); called by muse, mutect2
- IGSF10 | c.3194C>A p.S1065Y | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- IL1RAP | c.1420C>A p.L474I | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- INMT | c.75C>A p.Y25* | Nonsense Mutation (SNP) | VAF 52/269 reads (19%) | called by muse, mutect2, varscan2
- IQCN | c.2779A>T p.I927F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- JAKMIP1 | c.1585del p.L529Cfs*2 | Frame Shift Del (DEL) | VAF 57/247 reads (23%) | called by mutect2, pindel, varscan2
- KCNK3 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA1549L | c.1514G>T p.W505L (on ENST00000321505; = p.W802L on NM_012194.3) | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KL | c.2190G>T p.L730F | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- KLK14 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRBA1 | c.1861G>T p.G621W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT3 | c.1870del p.Q624Sfs*83 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- KRT73 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KRTAP16-1 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LARP4B | c.1483A>T p.R495W | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- LARP7 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2
- LIN9 | c.691A>G p.R231G (on ENST00000366808 / NM_001270410.2; = p.R176G on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/364 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LOXHD1 | c.810C>A p.N270K | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- LRGUK | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 131/504 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- LRP1B | c.7834C>A p.Q2612K | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRP1B | c.7833C>A p.N2611K | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- LRRC4C | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC7 | c.3836G>A p.G1279D (on ENST00000651989 / NM_001370785.2; = p.G1246D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LTBP1 | c.2794G>T p.E932* (on ENST00000404816 / NM_206943.4; = p.E606* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 80/328 reads (24%) | called by muse, mutect2, varscan2
- MAPK14 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 92/364 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK15 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2
- MAST1 | c.1423C>A p.R475S | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MDGA2 | c.1819+2T>C p.X607_splice (on ENST00000399232 / NM_001113498.2; = p.X309_splice on NM_182830.4) | Splice Site (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- MEA1 | c.251_254del p.L84Hfs*8 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- MED14 | c.1651-1G>T p.X551_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- MGRN1 | c.1531A>C p.T511P | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- MIGA1 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 86/376 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MKLN1 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTTP | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- MUC16 | c.2680C>A p.P894T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MUC22 | c.2089_2091del p.I697del | In Frame Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- MYH1 | c.5274G>T p.K1758N | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- NALCN | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2
- NFATC1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NLRP12 | c.1454G>C p.G485A | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NMNAT2 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2
- NRXN1 | c.3283C>A p.Q1095K | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- NUTM1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- OR10T2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR11L1 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OR14A2 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- OR1M1 | c.827T>A p.V276E | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2D2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- OR2M5 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 191/415 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- OR2T8 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51D1 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR7A17 | c.242T>C p.M81T | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PCDHB9 | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGR | c.2213-1G>T p.X738_splice | Splice Site (SNP) | VAF 52/263 reads (20%) | called by muse, mutect2, varscan2
- PHF6 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3AP1 | c.1311del p.G438Afs*47 | Frame Shift Del (DEL) | VAF 104/323 reads (32%) | called by mutect2, pindel, varscan2
- PLA2G4A | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLBD2 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLCB4 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 96/277 reads (35%) | called by muse, mutect2, varscan2
- POTEB3 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by mutect2, varscan2
- PPFIA2 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPP2R2C | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PPP4R3C | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PROS1 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGIS | c.1327G>T p.G443W | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL1 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS6 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNF150 | c.1082C>A p.T361K | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ROPN1L | c.594-1G>T p.X198_splice | Splice Site (SNP) | VAF 131/228 reads (57%) | called by muse, mutect2, varscan2
- RORB | c.1039G>A p.D347N (on ENST00000396204 / NM_001365023.1; = p.D336N on NM_006914.4) | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RTTN | c.1214T>G p.V405G | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SCN7A | c.4963G>T p.D1655Y | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SEMA6B | c.1760C>A p.S587Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SH2B2 | c.987G>T p.L329F | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SI | c.5421A>T p.L1807F | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SIM1 | c.521del p.G174Afs*16 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- SLC14A2 | c.2201T>C p.I734T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- SLC16A13 | c.842C>A p.T281K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC39A2 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC7A1 | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC8A3 | c.2092T>C p.W698R (on ENST00000381269 / NM_183002.3; = p.W696R on NM_033262.4) | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SNAP25 | c.255C>G p.C85W | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS1 | c.967A>T p.M323L | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by mutect2, varscan2
- SP140L | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SPART | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTA1 | c.3393G>T p.E1131D | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPTA1 | c.2821C>T p.H941Y | Missense Mutation (SNP) | VAF 282/626 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STYXL2 | c.2227C>A p.L743M | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SUSD1 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SV2C | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TACC1 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 79/358 reads (22%) | called by muse, mutect2, varscan2
- TAS2R41 | c.869T>A p.L290H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D1 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 63/295 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TBX20 | c.660T>G p.I220M | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBXAS1 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TCERG1L | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TCP11X2 | c.828C>A p.S276R | Missense Mutation (SNP) | VAF 142/1160 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, varscan2
- TDRD6 | c.1784T>G p.I595R | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TENM1 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TEX13C | c.1492G>T p.G498W | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THADA | c.4594G>T p.A1532S | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMED7 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, mutect2
- TMTC2 | c.634A>T p.I212L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, varscan2
- TNRC6A | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 60/249 reads (24%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV8-3 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TTN | c.85730C>A p.T28577K (on ENST00000591111; = p.T21153K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.22076G>A p.S7359N (on ENST00000591111; = p.S6432N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/151 reads (11%) | PolyPhen benign (0.044); called by muse, varscan2
- UBTFL1 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UGT1A1 | c.1172T>A p.M391K | Missense Mutation (SNP) | VAF 141/511 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- VIL1 | c.1532C>A p.T511N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VNN3 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.185); called by muse, mutect2
- XYLT1 | c.2321del p.K774Rfs*5 | Frame Shift Del (DEL) | VAF 44/189 reads (23%) | called by mutect2, pindel, varscan2
- YTHDC1 | c.1371G>T p.K457N (on ENST00000344157 / NM_001031732.4; = p.K439N on NM_133370.4) | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ZBBX | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 125/398 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZEB1 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 165/543 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ZEB2 | c.2639C>A p.T880N | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZHX2 | c.1906dup p.S636Kfs*36 | Frame Shift Ins (INS) | VAF 53/294 reads (18%) | called by mutect2, pindel, varscan2
- ZIC4 | c.626C>A p.P209Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF253 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF366 | c.1849C>A p.H617N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF438 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF804A | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF831 | c.1859G>T p.W620L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF92 | c.862G>T p.E288* (on ENST00000328747 / NM_152626.4; = p.E219* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.1801_1809del p.W601_G603del | In Frame Del (DEL) | VAF 38/181 reads (21%) | called by mutect2, pindel, varscan2
- ZXDB | c.1684C>A p.H562N | Missense Mutation (SNP) | VAF 18/383 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- ZYG11A | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ADCY8 | c.2538C>A p.T846= | Silent (SNP) | VAF 61/212 reads (29%) | catalogued as COSV53912354; called by muse, mutect2, varscan2
- ADGRL3 | c.3858G>T p.P1286= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as rs578181532; called by muse, mutect2, varscan2
- AHNAK2 | c.7674G>A p.E2558= | Silent (SNP) | VAF 15/238 reads (6%) | catalogued as COSV60915978; called by muse, mutect2
- AKAP4 | c.1185G>T p.G395= | Silent (SNP) | VAF 66/158 reads (42%) | called by mutect2, varscan2
- ANKRD17 | c.7251G>C p.V2417= | Silent (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- ASGR1 | c.465G>A p.P155= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- ATP8A2 | c.492C>A p.T164= | Silent (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- BANP | c.573G>T p.G191= (on ENST00000286122; = p.G160= on NM_017869.4) | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1268895700; called by muse, mutect2, varscan2
- C4orf51 | c.114A>C p.T38= | Silent (SNP) | VAF 60/522 reads (11%) | called by muse, mutect2, varscan2
- CACNA1A | c.3966A>T p.I1322= | Silent (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- CADPS2 | c.1914C>G p.P638= | Silent (SNP) | VAF 92/427 reads (22%) | called by muse, mutect2, varscan2
- CATSPER1 | c.2271C>A p.R757= | Silent (SNP) | VAF 64/259 reads (25%) | called by muse, mutect2, varscan2
- CCDC168 | c.15129C>A p.L5043= | Silent (SNP) | VAF 83/187 reads (44%) | called by muse, mutect2, varscan2
- CFAP58 | c.2283A>G p.L761= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1215G>C p.G405= | Silent (SNP) | VAF 88/178 reads (49%) | called by muse, mutect2, varscan2
- COL20A1 | c.1416G>A p.A472= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs771133641, COSV58911130, COSV58927522; called by muse, mutect2, varscan2
- COL3A1 | c.351T>A p.P117= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as COSV58592713; called by muse, mutect2, varscan2
- COL4A3 | c.876C>T p.D292= | Silent (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- COL6A5 | c.2844C>A p.I948= | Silent (SNP) | VAF 30/398 reads (8%) | called by muse, mutect2
- CTNNA3 | c.1572C>A p.A524= | Silent (SNP) | VAF 40/387 reads (10%) | called by muse, mutect2, varscan2
- CUBN | c.10194C>T p.D3398= | Silent (SNP) | VAF 29/407 reads (7%) | catalogued as rs542073853, COSV64715990; called by muse, mutect2
- DAPK3 | c.1266G>A p.A422= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs756397002; called by muse, mutect2, varscan2
- DCAF5 | c.1251C>T p.A417= | Silent (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2
- DDX54 | c.273G>A p.K91= | Silent (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- DGKK | c.918C>A p.T306= | Silent (SNP) | VAF 86/228 reads (38%) | called by muse, mutect2, varscan2
- DISC1 | c.333G>T p.V111= | Silent (SNP) | VAF 42/398 reads (11%) | called by muse, mutect2, varscan2
- EDEM2 | c.1311C>T p.L437= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV63259781; called by muse, mutect2, varscan2
- FBL | c.159C>T p.G53= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs773276717, COSV55681466; called by muse, mutect2
- FLNC | c.7707C>A p.G2569= | Silent (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- FLT3 | c.1152C>A p.T384= | Silent (SNP) | VAF 80/223 reads (36%) | called by muse, mutect2, varscan2
- FREM3 | c.4926A>G p.T1642= | Silent (SNP) | VAF 77/256 reads (30%) | called by muse, mutect2, varscan2
- FSIP2 | c.14763A>G p.A4921= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- FST | c.435C>A p.L145= | Silent (SNP) | VAF 84/349 reads (24%) | called by muse, mutect2, varscan2
- GIMAP6 | c.360C>A p.A120= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- GMPR | c.435C>G p.V145= | Silent (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- GZMK | c.279C>A p.S93= | Silent (SNP) | VAF 57/339 reads (17%) | catalogued as COSV99141028; called by muse, mutect2, varscan2
- HCN1 | c.1494T>G p.P498= | Silent (SNP) | VAF 67/937 reads (7%) | called by muse, mutect2
- HMCN1 | c.16365C>T p.C5455= | Silent (SNP) | VAF 53/506 reads (10%) | called by muse, mutect2, varscan2
- HMCN2 | c.5394C>A p.A1798= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- IFT57 | c.1200A>C p.T400= | Silent (SNP) | VAF 52/202 reads (26%) | called by muse, mutect2, varscan2
- IGSF9B | c.1014G>T p.V338= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- IL21R | c.90C>A p.L30= | Silent (SNP) | VAF 39/182 reads (21%) | called by muse, mutect2, varscan2
- INSIG2 | c.513G>T p.L171= | Silent (SNP) | VAF 95/319 reads (30%) | called by muse, mutect2, varscan2
- INSYN2B | c.969A>T p.P323= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- IQGAP3 | c.2796T>C p.D932= | Silent (SNP) | VAF 46/314 reads (15%) | called by muse, mutect2, varscan2
- KCNA7 | c.939C>A p.G313= | Silent (SNP) | VAF 68/146 reads (47%) | called by muse, mutect2, varscan2
- KIF19 | c.1011G>T p.L337= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- KIF7 | c.3028C>T p.L1010= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- KRTAP5-4 | c.261C>A p.S87= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1337694300; called by muse, mutect2, varscan2
- LAMA2 | c.9033C>G p.V3011= | Silent (SNP) | VAF 43/434 reads (10%) | called by muse, mutect2
- MANBA | c.756C>T p.I252= | Silent (SNP) | VAF 50/272 reads (18%) | catalogued as rs779421094, COSV56966492; called by muse, mutect2, varscan2
- MBD1 | c.306C>T p.P102= | Silent (SNP) | VAF 67/355 reads (19%) | called by muse, mutect2, varscan2
- MTTP | c.1074G>A p.Q358= | Silent (SNP) | VAF 64/447 reads (14%) | called by muse, mutect2, varscan2
- MUC12 | c.1860C>G p.T620= (on ENST00000379442; = p.T477= on NM_001164462.1) | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as rs1239944290, COSV65187994; called by muse, mutect2
- MYBPH | c.21C>G p.S7= | Silent (SNP) | VAF 120/208 reads (58%) | catalogued as COSV104370775; called by muse, mutect2, varscan2
- NKAPL | c.222G>T p.R74= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- OR4D2 | c.753C>T p.F251= | Silent (SNP) | VAF 143/522 reads (27%) | catalogued as rs781540142, COSV73459786; called by muse, mutect2, varscan2
- OTOG | c.5040G>T p.L1680= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- PCTP | c.204G>T p.L68= | Silent (SNP) | VAF 54/258 reads (21%) | called by muse, mutect2, varscan2
- PDYN | c.336C>G p.L112= | Silent (SNP) | VAF 101/506 reads (20%) | catalogued as COSV54101848, COSV54102860; called by muse, mutect2, varscan2
- POM121L12 | c.369G>T p.G123= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV101374984, COSV68692653; called by muse, mutect2, varscan2
- PROM2 | c.1591C>T p.L531= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- PRUNE2 | c.642G>A p.E214= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV65029366; called by muse, mutect2, varscan2
- PTPRD | c.81A>T p.T27= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- ROBO4 | c.648G>A p.R216= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs377431257; called by muse, mutect2, varscan2
- SAMSN1 | c.690G>A p.E230= (on ENST00000647101; = p.E2= on NM_001256370.1) | Silent (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- SAMSN1 | c.576G>C p.P192= | Silent (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- SCAF1 | c.2268C>T p.A756= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1191637310; called by muse, mutect2
- SCN7A | c.963G>A p.V321= | Silent (SNP) | VAF 69/215 reads (32%) | called by muse, mutect2, varscan2
- SEMA6B | c.1761C>A p.S587= | Silent (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- SETD1A | c.1278G>T p.R426= | Silent (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- SHANK1 | c.3840G>T p.P1280= | Silent (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- SIRPB1 | c.717T>A p.L239= | Silent (SNP) | VAF 57/251 reads (23%) | called by muse, mutect2, varscan2
- SLC1A2 | c.1551C>A p.T517= | Silent (SNP) | VAF 98/392 reads (25%) | catalogued as rs776103276; called by muse, mutect2, varscan2
- SLC25A12 | c.942G>T p.G314= | Silent (SNP) | VAF 87/496 reads (18%) | catalogued as rs752010390; called by muse, mutect2, varscan2
- SPATA31D4 | c.2532T>A p.P844= | Silent (SNP) | VAF 39/168 reads (23%) | called by mutect2, varscan2
- SPTBN4 | c.2301G>A p.R767= | Silent (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- TAS2R38 | c.873T>A p.S291= | Silent (SNP) | VAF 88/270 reads (33%) | called by muse, mutect2, varscan2
- UBR4 | c.13347C>T p.G4449= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as rs1251639743, COSV64392367; called by muse, mutect2, varscan2
- UNC80 | c.4998A>T p.A1666= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.7371A>C p.T2457= | Silent (SNP) | VAF 30/736 reads (4%) | called by muse, mutect2
- VIT | c.1060C>A p.R354= (on ENST00000389975 / NM_001177969.1; = p.R369= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/308 reads (25%) | catalogued as rs377073906, COSV64895453, COSV64896966; called by muse, varscan2
- ZBTB14 | c.1272G>A p.Q424= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as rs1454380693; called by muse, mutect2, varscan2
- ZMAT4 | c.444G>T p.G148= | Silent (SNP) | VAF 104/397 reads (26%) | called by muse, mutect2, varscan2
- ZNF469 | c.9771C>T p.A3257= (on ENST00000437464; = p.A3285= on NM_001367624.2) | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- ZNF536 | c.3651C>A p.P1217= | Silent (SNP) | VAF 56/119 reads (47%) | catalogued as rs201688634, COSV100835119, COSV62822661; called by muse, mutect2, varscan2
- AAMP | c.122-30C>T | Intron (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- ABCC6P1 | n.913dup | RNA (INS) | VAF 51/188 reads (27%) | called by mutect2, varscan2
- AC004951.2 | n.119C>G | RNA (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2
- AC025278.3 | n.79G>T | RNA (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- AC136604.1 | n.627G>C | RNA (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1168G>A | RNA (SNP) | VAF 68/365 reads (19%) | catalogued as rs756517723; called by muse, mutect2, varscan2
- ADCY10P1 | n.3638-625T>A | Intron (SNP) | VAF 38/116 reads (33%) | called by muse, varscan2
- AP001042.1 | n.2424T>C | RNA (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP8 | c.299+238G>T | Intron (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- CELF3 | c.*264C>A | 3'UTR (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- CHRNA4 | c.*1947G>T | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, varscan2
- CSMD3 | c.178+59968C>T | Intron (SNP) | VAF 18/366 reads (5%) | catalogued as COSV52330392; called by muse, mutect2
- CTDP1 | chr18:79679494 G>A | 5'Flank (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- DAAM2 | c.*2685C>G | 3'UTR (SNP) | VAF 63/226 reads (28%) | called by muse, mutect2, varscan2
- DNAH8 | c.-86C>A | 5'UTR (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- DYSF | c.-21G>T | 5'UTR (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- EP400P1 | n.485G>A | RNA (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- FAM220BP | n.463C>T | RNA (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1035G>T | RNA (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2
- GAS1 | c.-18C>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- GPM6A | c.37+24811G>C | Intron (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102460A>T | Intron (SNP) | VAF 44/154 reads (29%) | called by muse, mutect2, varscan2
- HDGF | c.*26C>T | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- HTR3A | c.265-16C>A | Intron (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- ICE1 | c.178+24G>A | Intron (SNP) | VAF 32/444 reads (7%) | called by muse, mutect2
- IER3IP1 | c.193+17A>T | Intron (SNP) | VAF 85/386 reads (22%) | called by muse, mutect2, varscan2
- MIR124-2HG | n.340T>C | RNA (SNP) | VAF 67/216 reads (31%) | catalogued as rs1028874380; called by muse, mutect2, varscan2
- MKRN9P | n.391G>T | RNA (SNP) | VAF 141/439 reads (32%) | called by muse, mutect2, varscan2
- NDUFB11 | c.-12G>C | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- OPRM1 | c.-15C>A | 5'UTR (SNP) | VAF 35/121 reads (29%) | catalogued as COSV57674931; called by muse, mutect2, varscan2
- OPRM1 | c.-14C>A | 5'UTR (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- OR7E5P | n.663G>T | RNA (SNP) | VAF 63/226 reads (28%) | called by muse, mutect2, varscan2
- PDE8B | c.*30G>C | 3'UTR (SNP) | VAF 17/286 reads (6%) | called by muse, mutect2
- POTEG | c.811-1205C>A | Intron (SNP) | VAF 47/531 reads (9%) | called by muse, varscan2
- PRDM15 | c.1564+909G>T | Intron (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- PTPRN | c.*5C>A | 3'UTR (SNP) | VAF 11/89 reads (12%) | called by muse, varscan2
- REXO1L1P | n.1514G>A | RNA (SNP) | VAF 66/2260 reads (3%) | catalogued as rs1229658728; called by muse, mutect2
- RP9 | c.313+43C>T | Intron (SNP) | VAF 70/310 reads (23%) | called by muse, mutect2, varscan2
- RSRC1 | c.652+8345G>T | Intron (SNP) | VAF 47/208 reads (23%) | called by muse, mutect2, varscan2
- SEMA4C | c.110-248G>C | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs1475912050; called by muse, mutect2, varscan2
- SERPING1 | c.1029+169G>T | Intron (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- SFTA3 | n.810-693G>C | Intron (SNP) | VAF 23/280 reads (8%) | catalogued as rs1190513906; called by muse, mutect2
- SNORD115-14 | n.12G>T | RNA (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088090 G>T | 3'Flank (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-178C>G | 5'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- TBC1D3P2 | n.267del | RNA (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel*, varscan2
- THAP4 | c.-11C>T | 5'UTR (SNP) | VAF 15/67 reads (22%) | catalogued as rs1418202004; called by muse, mutect2, varscan2
- TRIML2 | c.746-881G>A | Intron (SNP) | VAF 50/199 reads (25%) | called by muse, mutect2, varscan2
- UBBP4 | n.1064T>G | RNA (SNP) | VAF 33/269 reads (12%) | called by muse, mutect2, varscan2
- UBBP4 | n.1065G>T | RNA (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- UBE2DNL | n.627G>A | RNA (SNP) | VAF 19/46 reads (41%) | catalogued as rs1451079701; called by muse, mutect2, varscan2
- UBTFL2 | n.882G>C | RNA (SNP) | VAF 82/398 reads (21%) | called by muse, mutect2, varscan2
- UXT | chrX:47659906 A>G | 5'Flank (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4136G>A | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- ZNF333 | c.-7C>T | 5'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- ZNF849P | n.419C>A | RNA (SNP) | VAF 59/164 reads (36%) | called by muse, mutect2, varscan2
